Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A49G, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A49G-01A (Primary Tumor).

[page 1 of 5]
Referring Physician:

DOB:

Age:

Gender: F

Ref#:

Hosp#:

Provider Group:

Date of Service:

Date Received:

Inpatient

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. & C.) WHIPPLE CONTENTS AND NEW PANCREATIC MARGIN, WHIPPLE RESECTION AND RE-EXCISION OF PANCREATIC MARGIN:

- INVASIVE MODERATELY DIFFERENTIATED DUCTAL ADENOCARCINOMA INVOLVING THE HEAD OF THE PANCREAS, 3 CM IN GREATEST DIMENSION.
- TUMOR FOCALLY INVOLVES UNCINATE MARGIN.
- REMAINING MARGINS (COMMON BILE DUCT MARGIN, FINAL PANCREATIC RESECTION MARGIN, GASTRIC AND DUODENAL MARGINS) ARE NEGATIVE FOR TUMOR.
- NO DEFINITIVE LYMPHOVASCULAR INVASION IDENTIFIED.
- FOCAL PERINEURAL INVASION IDENTIFIED.
- METASTATIC CARCINOMA IDENTIFIED IN THREE OF EIGHTEEN LYMPH NODES (3/18).
- NO EXTRANODAL EXTENSION IDENTIFIED.
- FEW ATYPICAL CELLS IDENTIFIED IN THREE ADDITIONAL NODES, INDEFINITE FOR TUMOR CELLS.
- PANCREATIC INTRAEPITHELIAL NEOPLASIA (PanIN-2) IDENTIFIED.
- BENIGN PORTION OF STOMACH AND DUODENUM.

B. GALLBLADDER, CHOLECYSTECTOMY:

- CHRONIC CHOLECYSTITIS AND CHOLELITHIASIS.
- ONE UNREMARKABLE ISOLATED LYMPH NODE.
- NEGATIVE FOR DYSPLASIA.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade (invasive): Pancreatic ductal adenocarcinoma, moderately differentiated.

Primary tumor: pT2.

Regional lymph nodes: pN1.

Distant metastasis: N/A.

Stage: IIB.

ICD-0-3
adenocarcinoma, duct, NOS 8500/3
Site: pancreas, head C25.0

fw 9/27/12

Tumor Staging Information

Page 1

This report continues... (FINAL)

[page 2 of 5]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol.

Specimen:

Whipple contents.

Procedure:

Whipple resection.

TUMOR FEATURES:

Tumor site:

Head of pancreas.

Tumor size:

3 x 2.3 x 1.8 cm.

Histologic type:

Ductal adenocarcinoma.

Histologic grade:

Moderately differentiated.

Microscopic tumor extension:

Tumor focally involves uncinate margin.

MARGINS:

Tumor focally involves uncinate margin. Final pancreatic resection margin, bile duct margin, and gastric and duodenal margins are negative for tumor.

Treatment effect:

N/A.

Lymphovascular invasion:

Not identified.

Perineural invasion:

Not identified.

LYMPH NODES:

Metastatic carcinoma in 3 of 18 regional lymph nodes.

PATHOLOGIC TUMOR STAGING:

Primary tumor:

pT2.

Regional lymph nodes:

pN1.

Distant metastasis:

N/A.

Pathologic stage:

IIB.

Case #:

Page 2

Printed:

This report continues... (FINAL)

[page 3 of 5]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Whipple
- B. Gallbladder
- C. Pancreatic new margin

Clinical History/Operative Dx:

Pancreatic mass

The specimen is labeled as pancreatic new margin; suture marks new margin. Initially received in the fresh state for frozen section analysis is a portion of pancreas, 2.0 cm in length and 2.0 x 3.4 cm. A suture marks the new margin which is additionally marked blue. The new margin is trimmed and submitted en face for frozen section analysis with residual frozen tissue submitted in C1 for permanent sections. The pancreatic duct is 0.3 cm in diameter and probe patent. Sectioning demonstrates yellow-gray glandular parenchyma with mild hemorrhagic congestion and without grossly residual tumor. The remainder of the pancreas is submitted in a sequential fashion, proximal (old margin) to distal (new margin) in C2-C5. A scant amount of peripancreatic fat is examined and is suspicious for discrete lymph node content, sectioned and submitted in C6.

Intraoperative Diagnosis:

A. Whipple contents: Pancreatic margin positive for adenocarcinoma, bile duct margin is negative for carcinoma.

C. New pancreatic margin: Negative for carcinoma. intraoperative interpretation(s)
was/were performed and rendered at

Gross Description:

A. The specimen is labeled Whipple contents. Received in formalin, is a generous portion of tissue consistent with a Whipple procedure specimen: a distal resection of stomach, 5.7 cm lesser, 11.0 cm greater, a 25.5 cm length of duodenum averaging 3.3 cm in diameter, and the pancreas includes the head measuring 2.4 cm in length, 4.6 cm superior-inferior, and 4.6 cm anterior-posterior/uncinate margin. The gastric and small bowel segment demonstrates a semi-congested, light pink to deep red appearance. The pancreas is palpably soft to dense towards the superior-posterior periphery. The margins of the pancreas are now differentially inked as follows:

Anterior surface: Yellow,
Inferior surface: Green,
Superior margin: Blue,
Posterior margin/uncinate: Black,

Case #:

Page 3

Printed:

This report continues... (FINAL)

[page 4 of 5]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

Pancreatic notch surface: Red.

The common bile duct extends 1.3 and 0.9 cm in diameter, with a probe patent lumen into the small bowel segment. The pancreatic duct is unable to probe for patency with the CBD or small bowel lumen. The distal pancreatic margin is trimmed and submitted en face for frozen section analysis on one chuck with the residual frozen tissue submitted in A1 for permanent sections; the common bile duct margin is trimmed and submitted en face for frozen section analysis on a second chuck with the residual frozen tissue submitted in A2 for permanent sections.

The gastric and small bowel segments are now opened; the luminal contents are cleared revealing semi-congested, light pink to proximally deep red, gastric mucosa without discrete lesion. The small bowel segment demonstrates prominent, light pink and tan, circular plica that is increasingly softened and congested toward the distal margin of resection. The ampulla of Vater is oriented 5.3 cm distal to the pylorus and greater than 18.0 cm from the distal small bowel margin of resection. The ampulla demonstrates slightly raised and granular appearance. Initial sectioning through the pancreas reveals an ill-defined, dense, grossly fibrotic, light gray and pink, mass lesion, measuring upwards of 3.0 x 2.3 x 1.8 cm, and predominantly positioned in the superior-posterior aspect of the pancreas, within 0.1 cm of the superior, 0.3 cm of the posterior, 0.7 cm of the anterior margins, and within 0.1 cm of the surface of the pancreatic notch. The mass lesion appears to abut the common bile duct, however, the mucosa is glistening to wrinkled, light gray and deep red, without gross involvement. The lesion is grossly within 0.1 cm of the distal pancreatic margin, formally removed for frozen section analysis. The pancreatic duct narrows to 0.1 cm towards the small bowel length and is possibly obliterated by tumor. The grossly uninvolved pancreas demonstrates a pronounced, lobular-glandular, pink-yellow gross architecture, that becomes increasingly fatty towards the inferior anterior periphery.

Initial examination of the peripancreatic fat reveals twelve lymph node candidates ranging from 0.15 cm to 1.5 cm, rubbery, light gray to deep red. Initial examination of the perigastric fat does not reveal additional lymph node candidacy. Representative sections are submitted for microscopic evaluation.

Cassette summary:

- A1) distal pancreatic margin, FS,
- A2) common bile duct margin, FS,
- A3-A4) ampulla of Vater - pancreas, superior margin included,
- A5-A6) superior pancreas, tumor, edge of anterior margin,
- A7) additional anterior pancreas,
- A8-A9) pancreas - tumor - mesenteric groove/pancreatic notch surface,
- A10-A11) inferior pancreas,
- A12-A13) posterior/uncinate pancreas and tumor,
- A14) gastric tissue represented, two pieces,
- A15) small bowel length represented including additional representation of small bowel adjacent to ampulla of Vater,
- A16) proximal gastric margin of resection, represented,
- A17) distal small bowel margin of resection, trimmed and submitted,
- A18) five lymph node candidates,
- A19) three lymph node candidates,

Case #:

Printed:

Page 4

This report continues... (FINAL)

[page 5 of 5]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

- A20) single lymph node candidate, bisected,
A21) peripancreatic lymph node candidate, trisected,
A22) peripancreatic lymph node candidate, serially sectioned,
A23) peripancreatic lymph node candidate, serially sectioned.

B. The specimen is labeled gallbladder. Received in formalin is a previously disrupted, partially deflated gallbladder, 12.1 x 3.8 x 1.8 cm. The serosa is glistening, semi-congested and fatty, tan. The cystic duct margin demonstrates an obvious patent 5 mm lumen. A discrete cystic duct lymph node candidate is 2.5 mm. The wall is 0.1-0.3 cm with the submucosa appearing partially erythematous. The lumen contains residual dark green viscous bile without calculi. The mucosa is velvety, tan-green without grossly unusual areas of change suggestive of neoplasia. Representative sections are submitted to include submission of the lymph node candidate, cystic duct margin, and representation of the dome and mid fundus of the gallbladder in B1.

Microscopic Description:

A. - C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Intradepartmental consultation: reviewed selected slides and concurs.

Reviewed Initials	RM	8/30/12

Page 5

END OF REPORT (FINAL)

Case #:

Printed:

MR No.

Acct No. -

Patient Name -

Source: NCI Genomic Data Commons file 672ddc4e-eb2d-463f-8adb-2dafb7985056 (TCGA-HZ-A49G.B4B072E1-3592-4EBA-A4A4-F8AA591A2FFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).